Surgical pathology report (de-identified scan), TCGA case TCGA-31-1955, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1955-01A (Primary Tumor).

[page 1 of 3]
Consent: [REDACTED]

Specimen Type:

1: Uterus
2: OVARY RIGHT + LEFT

Clinical Details:

Ovarian cancer.

[REDACTED] TCGA-31-1955

Macroscopic Description:

1) UTERUS, OMENTUM

Uterus and cervix measuring 65 mm from side to side by 85 mm os to fundus by 34 mm anterior to posterior. The weight of uterus and cervix is 102.4 g. The cervix has a white glistening surface and the external os measures 20 mm. The maximum endometrial thickness is 2 mm and maximum myometrial thickness is 16 mm. The serosal surface has focal irregular areas, however, no definite tumour deposits seen.

A piece of omentum measuring 420 mm in length x 30 x 15 mm with multiple dark irregular pieces of tissue together measuring 60 x 60 x 15 mm. These pieces of tissue have a smooth glistening surface on one side. The omentum contains multiple white focal firm deposits.

BLOCK: A – anterior cervix, 1 pc.
B – posterior cervix, 1 pc.
C – anterior endometrium and myometrium, 1 pc.
D – posterior endometrium and myometrium, 1 pc.
E – endometrium, myometrium and irregular serosal surface, 1 pc.
F – fundus, 1 pc.
G – omental deposit, 1 pc.
H – omental deposit, 1 pc.
J – omental deposit, 1 pc.
K – omental deposit, 1 pc.
L – omental deposit, 1 pc.
M – section from dark irregular piece of tissue, 1 pc.

[page 2 of 3]
N – transverse section from dark irregular piece of tissue, 1 pc.

P – TS from dark irregular piece of tissue, 1 pc.

Q – TS from dark irregular piece of tissue, 1 pc.

2) RIGHT AND LEFT OVARIES

Both ovaries received in the same pot. The larger ovary measures 15 x 12 x 8 cm with attached fallopian tube measuring 5 cm. The weight of the specimen is 723 g. There are multiple granular areas on the ovarian surface. The largest granular area measures 2 cm. The cut surface is solid, irregular and green-coloured. The smaller ovary measures 13 x 10 x 8 cm. The weight of the specimen is 490 g. There is a grossly polypoid villous tumour perforating the capsule of this ovary measuring 6 x 4 cm. The cut surface of the ovary is solid, firm, irregular and pink-coloured. The external surfaces of both ovaries are inked blue.

BLOCKS: A – granular capsule deposit of larger ovary, 1 pc.
B – granular capsule deposit of larger ovary, 1 pc.
C – granular capsule deposit of larger ovary, 1 pc.
D – granular capsule deposit of larger ovary, 1 pc.
E – polypoid extension from capsule of larger ovary, 1 pc.
F – tumour to capsule, 1 pc.
G – tumour, 1 pc.
H and J – tumour to capsule, 1 pc. in each.
K – tumour, 1 pc.
L – tumour, 1 pc.
M – tumour to capsule, 1 pc.
N and P – tumour, 1 pc. in each (A to P are from the larger ovary).
Q – fallopian tube, larger ovary, 1 pc.
R – tumour growing through capsule, smaller ovary, 1 pc.
S – granular deposit, smaller ovary, 1 pc.
T – polypoid ...growth from capsule of small ovary, 1 pc.
U – polypoid .. growth from surface of small ovary, 1 pc.
V and W – tumour, smaller ovary, 1 pc.
X to Z – tumour to capsule, smaller ovary, 1 pc.
AA – tumour, smaller ovary, 1 pc.
BB – fallopian tube, smaller ovary, 1 pc.

TCGA-31-1955

Microscopic Description:

1. The cervix is normal. The endometrium is proliferative. The myometrium is normal. There are patchy serosal adhesions. In one of these, aggregates of tumour cells are seen within a vascular space. The omentum contains numerous deposits of serous papillary adenocarcinoma, grade 3. Occasional clusters of psammoma bodies are identified (eg block 1G). The separate dark irregular pieces of tissue (possibly tissue from the Pouch of Douglas) are also extensively involved by tumour.
2. Both ovaries are replaced by poorly differentiated adenocarcinoma. The tumour is composed of complex tubulopapillary glands, multifocally with solid cell groups. The tumour cells are highly pleomorphic, with large, vesicular nuclei and prominent nucleoli.

[page 3 of 3]
Numerous mitotic figures are present, including atypical forms. There is extensive necrosis. The features are most in keeping with a serous papillary adenocarcinoma of ovary, grade 3. There is extensive involvement of the surface of both ovaries (eg 2A, 2B, 2T). Both fallopian tubes are normal.

Final Diagnosis:

1. UTERUS, OMENTUM, TISSUE FROM THE POUCH OF DOUGLAS: OMENTUM AND SEPARATE TISSUE FRAGMENTS POSITIVE FOR SEROUS PAPILLARY ADENOCARCINOMA, GRADE 3. FOCAL LYMPHOVASCULAR INVASION BY TUMOUR, UTERINE SEROSAL SURFACE.
2. RIGHT AND LEFT OVARIES: PAPILLARY SEROUS CYSTADENOCARCINOMA, GRADE 3. BILATERAL. EXTENSIVE SURFACE INVOLVEMENT PRESENT. FIGO STAGE III C.

TCGA-31-1955

Additional Pathologist(s)/BMS(s)

Source: NCI Genomic Data Commons file 8e18bbe1-9b67-4cd4-b7eb-dfb32eab8a4a (TCGA-31-1955.16F5A24E-2C57-42FE-BD79-EF174D44B8B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).